Somatic mutation profile of tumor specimen C3N-01529-02 (aliquot CPT0097440009) from CPTAC case C3N-01529, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.0 years (25,559 days).
Specimen C3N-01529-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94f5f295-86a7-4b65-afb6-1adcdce6df58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01529-31 (Blood Derived Normal), aliquot CPT0097470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e244c6aa-43ad-4279-b5ce-6b553d4de809

The open-access MAF lists 98 somatic variants for this specimen: 74 protein-altering or splice-affecting, 15 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 15, Intron 5, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 2, 5'UTR 2, RNA 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.1113del p.Q372Sfs*19 | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | catalogued as rs875989848; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 73/176 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 77/172 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 259/643 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1052933001; called by muse, mutect2, varscan2
- AKT1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 152/188 reads (81%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); catalogued as COSV62573390; called by muse, mutect2, varscan2
- ARR3 | c.100+7G>A | Splice Region (SNP) | VAF 72/284 reads (25%) | catalogued as rs374227491; ClinVar: likely benign; called by mutect2, varscan2
- ASMTL | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 106/272 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs771748500, COSV99060215; called by muse, mutect2, varscan2
- CACNA1E | c.2771G>A p.R924H | Missense Mutation (SNP) | VAF 139/210 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs764081616, COSV100701288, COSV100705611; called by muse, mutect2, varscan2
- CSMD2 | c.6862G>A p.A2288T | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV53879842; called by muse, mutect2, varscan2
- DDOST | c.136C>G p.R46G (on ENST00000415136; = p.R29G on NM_005216.5) | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs150110141; called by muse, mutect2
- FGFR2 | c.1976A>T p.K659M | Missense Mutation (SNP) | VAF 124/350 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60656279; called by muse, mutect2, varscan2
- FGR | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759801265; called by muse, mutect2, varscan2
- FLG | c.3151C>T p.R1051C | Missense Mutation (SNP) | VAF 205/733 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs201961522, COSV64237239; called by muse, mutect2, varscan2
- GPR4 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 63/141 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs754537867; called by muse, mutect2, varscan2
- HAUS7 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV57850182; called by muse, mutect2, varscan2
- HSD17B10 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 181/425 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM070155; called by muse, mutect2, varscan2
- HSPG2 | c.3076G>A p.G1026R | Missense Mutation (SNP) | VAF 157/350 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.018); catalogued as rs1390312956; called by muse, mutect2, varscan2
- IGBP1 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 48/349 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs781617904, COSV60556084; called by muse, mutect2, varscan2
- KCNA10 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 177/421 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768535829, COSV63904462; called by muse, mutect2, varscan2
- MRGPRX1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 137/725 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); catalogued as rs767184906, COSV57106940; called by muse, mutect2, varscan2
- NEB | c.9815G>A p.R3272Q | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as rs748799656, COSV99424870; called by muse, mutect2, varscan2
- NOS2 | c.3182G>A p.R1061Q | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0.028); catalogued as rs201995183, COSV58222037; called by muse, mutect2, varscan2
- OR56A5 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as rs778078804, COSV60827030; called by muse, mutect2, varscan2
- PCDHB13 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV53394849; called by muse, mutect2, varscan2
- PMS1 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1397726140; called by muse, mutect2, varscan2
- PRKDC | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 142/340 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as rs761291525; called by muse, mutect2, varscan2
- RAB3GAP1 | c.815G>A p.C272Y | Missense Mutation (SNP) | VAF 203/461 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV51488439; called by muse, mutect2, varscan2
- RAI2 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1429779489, COSV100518247; called by muse, mutect2, varscan2
- SEMA3D | c.2243C>A p.P748Q | Missense Mutation (SNP) | VAF 161/360 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99406396; called by muse, mutect2, varscan2
- SNPH | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 155/381 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs144660706; called by muse, mutect2, varscan2
- SPOP | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 122/144 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV61653397, COSV61655511; called by muse, mutect2, varscan2
- ST3GAL1 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 79/162 reads (49%) | PolyPhen possibly damaging (0.532); catalogued as rs566201740; called by muse, mutect2, varscan2
- SYTL1 | c.1153C>A p.L385M (on ENST00000543823; = p.L373M on NM_032872.3) | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58870856; called by muse, varscan2
- TAB3 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.146); catalogued as rs1312085341; called by muse, mutect2, varscan2
- TFAP2A | c.265G>A p.A89T (on ENST00000482890; = p.A81T on NM_001032280.3) | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1309820486; called by mutect2, varscan2
- TOR4A | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs781116136; called by muse, mutect2, varscan2
- TRAV4 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1281804463; called by muse, mutect2, varscan2
- TRIM72 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 127/287 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs745904502, COSV57250624; called by muse, mutect2, varscan2
- VWF | c.4276C>T p.R1426C | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs555366738, CM163427, COSV54617848; called by muse, mutect2, varscan2
- ZSWIM3 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 155/387 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770362099; called by muse, mutect2, varscan2
- AHI1 | c.3426+7G>A | Splice Region (SNP) | VAF 39/186 reads (21%) | called by muse, mutect2, varscan2
- CASP6 | c.114A>C p.K38N | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CCDC168 | c.953A>T p.Q318L | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CHMP4C | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- F2R | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 173/422 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAPVD1 | c.2608A>G p.R870G (on ENST00000394104; = p.R897G on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 169/387 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1900G>A p.G634R | Missense Mutation (SNP) | VAF 176/816 reads (22%) | SIFT tolerated, low confidence (0.62); called by muse, mutect2, varscan2
- GPAT4 | c.78_80del p.L27del | In Frame Del (DEL) | VAF 104/252 reads (41%) | called by pindel, varscan2
- HM13 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 87/239 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HSF4 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- HSPA5 | c.1537G>C p.A513P | Missense Mutation (SNP) | VAF 92/297 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGKV1D-37 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by mutect2, varscan2
- LHX5 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- LRIG2 | c.2597_2601del p.Q866Rfs*6 | Frame Shift Del (DEL) | VAF 61/165 reads (37%) | called by mutect2, pindel, varscan2
- LYST | c.11273C>T p.T3758I | Missense Mutation (SNP) | VAF 308/518 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MORC2 | c.1844C>T p.S615L (on ENST00000397641 / NM_001303256.3; = p.S553L on NM_014941.3) | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- MTOR | c.5380G>A p.A1794T | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OBSCN | c.2576_2577del p.T859Sfs*6 | Frame Shift Del (DEL) | VAF 72/306 reads (24%) | called by pindel, varscan2
- OR14J1 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 114/236 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PANX2 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PKD1L1 | c.7499G>A p.S2500N | Missense Mutation (SNP) | VAF 151/359 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PTHLH | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 142/369 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.967); called by muse, varscan2
- SHROOM2 | c.4190C>T p.T1397I | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SLC20A1 | c.1082A>G p.Q361R | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.142); called by muse, mutect2
- SYN2 | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TDRD15 | c.2840C>A p.S947Y | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TFIP11 | c.2177G>A p.G726E | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- TRRAP | c.7807dup p.R2603Pfs*40 (on ENST00000359863 / NM_001244580.1; = p.R2585Pfs*40 on NM_003496.3) | Frame Shift Ins (INS) | VAF 67/166 reads (40%) | called by mutect2, pindel, varscan2
- TTC37 | c.2852T>C p.L951P | Missense Mutation (SNP) | VAF 17/473 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- ZFP36L2 | c.111dup p.T38Dfs*46 | Frame Shift Ins (INS) | VAF 98/260 reads (38%) | called by mutect2, pindel, varscan2
- ZNF208 | c.2779A>C p.S927R | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ZNF559 | c.1426A>G p.I476V | Missense Mutation (SNP) | VAF 128/306 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF787 | c.716A>G p.D239G | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH23 | c.7809C>T p.D2603= | Silent (SNP) | VAF 113/299 reads (38%) | catalogued as rs1384086625, COSV56474922; ClinVar: likely benign; called by muse, mutect2, varscan2
- DMD | c.2496C>T p.I832= | Silent (SNP) | VAF 194/483 reads (40%) | called by muse, mutect2, varscan2
- FRMD4B | c.39G>A p.L13= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV68332608; called by muse, mutect2, varscan2
- GSPT2 | c.234G>A p.Q78= | Silent (SNP) | VAF 51/122 reads (42%) | called by muse, mutect2, varscan2
- HS3ST1 | c.549G>A p.R183= | Silent (SNP) | VAF 135/347 reads (39%) | catalogued as rs768764336; called by muse, mutect2, varscan2
- INF2 | c.2154C>T p.I718= | Silent (SNP) | VAF 219/266 reads (82%) | catalogued as rs1324048827; called by muse, mutect2, varscan2
- IPPK | c.90C>T p.V30= | Silent (SNP) | VAF 67/179 reads (37%) | called by muse, mutect2, varscan2
- ITGB7 | c.1953T>C p.C651= | Silent (SNP) | VAF 104/243 reads (43%) | called by muse, mutect2, varscan2
- JARID2 | c.1272G>A p.G424= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as rs1207272282, COSV59184638; called by muse, mutect2, varscan2
- MYH11 | c.282G>A p.T94= | Silent (SNP) | VAF 134/328 reads (41%) | catalogued as rs759914132, COSV100260470; called by muse, mutect2, varscan2
- NDST4 | c.624C>A p.P208= | Silent (SNP) | VAF 123/302 reads (41%) | catalogued as COSV52140002; called by muse, mutect2, varscan2
- NETO1 | c.339A>C p.I113= | Silent (SNP) | VAF 131/321 reads (41%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1617G>A p.L539= | Silent (SNP) | VAF 276/729 reads (38%) | called by muse, varscan2
- RP1L1 | c.1293C>T p.H431= | Silent (SNP) | VAF 73/143 reads (51%) | catalogued as rs768404435, COSV66756535; called by muse, mutect2, varscan2
- UTP4 | c.1710G>A p.Q570= | Silent (SNP) | VAF 151/207 reads (73%) | called by muse, mutect2, varscan2
- ARPP21 | c.2032+544G>A | Intron (SNP) | VAF 17/121 reads (14%) | catalogued as COSV51792253, COSV99493548; called by muse, mutect2, varscan2
- C17orf49 | c.-38G>A | 5'UTR (SNP) | VAF 56/167 reads (34%) | called by muse, mutect2, varscan2
- FAM98C | c.65+59G>A | Intron (SNP) | VAF 14/209 reads (7%) | called by muse, mutect2
- INSRR | c.3397+29G>A | Intron (SNP) | VAF 75/856 reads (9%) | catalogued as rs777227609, COSV63870785; called by muse, mutect2
- IPO5 | c.-184A>T | 5'UTR (SNP) | VAF 120/285 reads (42%) | called by muse, mutect2, varscan2
- MT1B | chr16:56649448 C>T | 5'Flank (SNP) | VAF 119/159 reads (75%) | called by muse, mutect2, varscan2
- OR2L1P | n.945_979del | RNA (DEL) | VAF 61/338 reads (18%) | called by mutect2, pindel
- RLN1 | c.211+148dup | Intron (INS) | VAF 14/34 reads (41%) | called by mutect2, varscan2
- TCP11X2 | c.710-19del | Intron (DEL) | VAF 78/416 reads (19%) | called by mutect2, varscan2
